Somatic mutation profile of tumor specimen TARGET-10-PATLHH-09A (aliquot TARGET-10-PATLHH-09A-01D) from TARGET case TARGET-10-PATLHH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.7 years (2,830 days).
Specimen TARGET-10-PATLHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64409520-8067-412c-ab51-b7ceb2934074.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATLHH-10A (Blood Derived Normal), aliquot TARGET-10-PATLHH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/853b4bc4-889f-4325-a9bf-75851c460228

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 4, Silent 3, Intron 3, 5'UTR 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 14/133 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.5252C>T p.T1751M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs753874423, COSV52458559; called by muse, mutect2, varscan2
- DNAH17 | c.4048G>A p.V1350M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs373436522; called by muse, mutect2, varscan2
- FAM53A | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs775633001, COSV57400480; called by muse, mutect2, varscan2
- GCKR | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs758692756, COSV53020757; called by muse, mutect2, varscan2
- HEG1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772002458, COSV60759766; called by muse, mutect2, varscan2
- LCE2B | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs575837944, COSV64227423; called by muse, mutect2, varscan2
- OR4A16 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs144905099, COSV59044107; called by muse, mutect2, varscan2
- XPC | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV53203748; called by muse, mutect2, varscan2
- HYDIN | c.13552C>T p.L4518F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MARCHF6 | c.37_38insAGTCTTTC p.R13Qfs*31 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- PTAR1 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); called by muse, mutect2
- TRRAP | c.2481_2482insTCC p.L827_M828insS | In Frame Ins (INS) | VAF 40/116 reads (34%) | called by mutect2, pindel*, varscan2
- IGSF1 | c.1812G>A p.P604= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as rs780114018; called by muse, mutect2, varscan2
- KMT2A | c.7074G>A p.S2358= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as rs192173056, COSV63291928; called by muse, mutect2, varscan2
- MRPS9 | c.180C>T p.N60= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1236959048, COSV99306495; called by muse, mutect2, varscan2
- AC012236.1 | n.295G>A | RNA (SNP) | VAF 4/42 reads (10%) | catalogued as rs1005133006; called by muse, mutect2, varscan2
- CEP57 | c.885+16_885+17insAACTCTTACTCGTC | Intron (INS) | VAF 16/57 reads (28%) | catalogued as COSV57687458; called by mutect2, pindel, varscan2
- ERCC8 | c.*135G>A | 3'UTR (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- FAM160A1 | c.-20G>A | 5'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs1401245849; called by mutect2, varscan2
- GNAL | c.*11G>A | 3'UTR (SNP) | VAF 11/30 reads (37%) | catalogued as rs755679575, COSV52324887; called by muse, mutect2, varscan2
- MARCHF7 | c.*121A>G | 3'UTR (SNP) | VAF 5/16 reads (31%) | catalogued as rs1185666505; called by muse, mutect2, varscan2
- PAPLN | c.2724-162T>A | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- SYT13 | c.184-13526G>T | Intron (SNP) | VAF 36/110 reads (33%) | called by muse, mutect2, varscan2
- WWOX | c.*323T>C | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
